Surgical pathology report (de-identified scan), TCGA case TCGA-60-2706, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2706-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. RIGHT UPPER LOBE
B. 10 R LN

CLINICAL HISTORY:

CT positive spiculated 1.1cm. mass suspicious for malignancy

PRE-OPERATIVE DIAGNOSIS:

Right upper lobe mass

FROZEN SECTION DIAGNOSIS:

A. LUNG,RIGHT UPPER LOBE,LOBECTOMY:
Non small cell carcinoma, favor squamous cell carcinoma by

GROSS DESCRIPTION:

A. LUNG,RIGHT UPPER LOBE,LOBECTOMY:

Received fresh is right upper lobectomy specimen weighing 244 gm and measuring 16x 14.5x 3 cm. There is a stapled margin at the upper part. Opposite the hilar area there is a firm nodular mass measuring 2x2x1.8cm. On cut sections tumor has a well circumscribed tan grey white, granular cut surface. The rest of the specimen shows anthracosis, congestion, and atelectatic change. Sections taken from bronchial margin (frozen section-Fsa 1-negative for tumor; Fsa2-section from tumor-non-small cell carcinoma by Multiple sections submitted as follows:

- A3: section from bronchus
- A4: tumor
- A5: pleura overlying tumor
- A6-A7: tumor
- A8-A9: uninvolved lung
- A11-A12: lymph nodes

[page 2 of 2]
B. 10R LYMPH NODE

Specimen consists of a round portion of soft tissue with is heavily stapled measuring .6x.6x.1cm.
A portion is submitted as B1.

DIAGNOSIS:

A. LUNG, RIGHT UPPER LOBE, LOBECTOMY:

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF UPPER LOBE OF RIGHT LUNG
- SIZE OF TUMOR -2X2X1.8CM.
- BRONCHIAL MARGINS OF RESECTION- FREE OF TUMOR
- TWO PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR TUMOR (0/2)
- CONGESTION OF LUNG
- FOCAL INTERSTITIAL FIBROSIS

B.10 RIGHT LYMPHNODE-SMALL FRAGMENT OF LUNG TISSUE WITH
CONGESTION-NEGATIVE FOR TUMOR(no lymphnode identified)

Lung template

1. Tumor type: Squamous cell carcinoma
2. Histologic grade: Poorly differentiated
3. Tumor location: Peripheral
4. Tumor size: 2x2x1.8cm.
5. Angiolymphatic invasion: Absent
6. Perineural invasion: Absent
7. Involvement of main stem bronchus: Absent
8. Bronchial margin: Negative
9. Visceral pleural margin: Negative
10. Hilar lymph nodes: (peribronchial): Negative (0/02)
11. In-situ carcinoma: Absent
12. Pathologic stage: pT1N0
13. Non-neoplastic lung: NG
-

Source: NCI Genomic Data Commons file aaf9dbad-e121-4e0d-86f2-111368d0536e (TCGA-60-2706.94622916-D2D7-44DA-8013-437E4370DC96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).